Somatic mutation profile of tumor specimen TCGA-FP-A4BE-01A (aliquot TCGA-FP-A4BE-01A-12D-A24D-08) from TCGA case TCGA-FP-A4BE, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 55.2 years (20,148 days).
Specimen TCGA-FP-A4BE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7108730-04c7-47fa-a514-678e75040809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-A4BE-11A (Solid Tissue Normal), aliquot TCGA-FP-A4BE-11A-11D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/699d4348-709d-4cca-9cb4-91bc0760a1f5

The open-access MAF lists 1,731 somatic variants for this specimen: 1,332 protein-altering or splice-affecting, 364 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 912, Silent 364, Frame Shift Del 267, Frame Shift Ins 63, Nonsense Mutation 50, Splice Site 24, Intron 19, In Frame Del 9, 3'UTR 8, RNA 5, Splice Region 5, 3'Flank 2.

Variants (750 of 1,731; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- COL7A1 | c.7865G>A p.R2622Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs368529673, CD096575, CM071635, COSV56477245; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*3904C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | catalogued as rs367543063, CM122714, COSV57058366; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- EGFR | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 43/118 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs760101437, COSV51785413, COSV51800797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGFR3 | c.*194G>A | 3'UTR (SNP) | VAF 89/252 reads (35%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- GALK1 | c.410del p.G137Vfs*27 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs767329054, CD993840; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- GBA2 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as rs774411642, COSV62305671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 29/106 reads (27%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KNSTRN | c.64T>A p.C22S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV51104894; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MLH1 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs63751310, CD962077, CM960973, COSV51616216, COSV51619199; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 38/126 reads (30%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MTHFR | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs786204023, CM155629, COSV64877535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 68/203 reads (33%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- PAFAH1B1 | c.910del p.S304Vfs*29 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs587784292; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH15 | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as rs773404494, COSV57299069; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 56/91 reads (62%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 53/105 reads (50%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TCIRG1 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as rs1489993984, CM1210303, COSV55835271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 27/88 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1333T>C p.F445L | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV55289676; called by muse, mutect2, varscan2
- ABCC2 | c.890del p.K297Rfs*14 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | catalogued as rs759781877; called by mutect2, varscan2
- ABCC5 | c.3281C>T p.A1094V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs778463808, COSV55589262; called by muse, varscan2
- ABCD3 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1474170733, COSV64642789; called by muse, mutect2, varscan2
- ABCF2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55182510; called by muse, mutect2, varscan2
- ABCF3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.069); catalogued as rs747252180, COSV53047854; called by muse, mutect2, varscan2
- ABHD17A | c.542C>T p.P181L (on ENST00000292577 / NM_001130111.2; = p.P232L on NM_031213.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.213); catalogued as COSV51750389; called by muse, mutect2, varscan2
- ABI3BP | c.1267A>G p.R423G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52534627, COSV52546092; called by muse, varscan2
- AC011462.1 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as CM159332, COSV54196759; called by muse, mutect2, varscan2
- AC244197.3 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61712111; called by muse, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as rs757016425; called by mutect2, varscan2
- ACCSL | c.1470+2T>C p.X490_splice | Splice Site (SNP) | VAF 52/143 reads (36%) | catalogued as COSV66581060; called by muse, mutect2, varscan2
- ACOT1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768462704, COSV58572097; called by muse, mutect2, varscan2
- ACOT1 | c.722T>C p.M241T | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776778694, COSV100233363; called by muse, mutect2, varscan2
- ACSM5 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750548939, COSV59371010; called by muse, mutect2, varscan2
- ACTR8 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.961); catalogued as rs149202945; called by mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM20 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56454829; called by muse, mutect2, varscan2
- ADAMTS13 | c.4042G>A p.A1348T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs587682066, COSV52469688; called by muse, mutect2, varscan2
- ADAMTS14 | c.1352+1G>A p.X451_splice | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as rs530033822, COSV64601558; called by muse, mutect2, varscan2
- ADAMTS15 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1278039232, COSV54504964; called by muse, mutect2, varscan2
- ADAMTS3 | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372067284, COSV54390003; called by muse, mutect2, varscan2
- ADAT1 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs752025717, COSV57186294; called by muse, mutect2, varscan2
- ADCY9 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV53574460; called by muse, mutect2, varscan2
- ADD3 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV53321966; called by muse, mutect2, varscan2
- ADGRB2 | c.3552G>T p.Q1184H | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57072973; called by muse, mutect2, varscan2
- ADH1C | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 126/463 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV72463427, COSV72463447; called by muse, mutect2, varscan2
- ADRA2C | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467182; called by muse, mutect2, varscan2
- ADRB3 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61461861; called by muse, mutect2, varscan2
- AFF4 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1205979521, COSV54794177; called by muse, mutect2, varscan2
- AFM | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs536766988, COSV56919890; called by muse, mutect2, varscan2
- AGAP2 | c.1804G>A p.G602R (on ENST00000547588 / NM_001122772.2; = p.G266R on NM_014770.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs771629262, COSV57727884, COSV57731942, COSV99223201; called by muse, mutect2, varscan2
- AGAP2 | c.1781C>T p.P594L (on ENST00000547588 / NM_001122772.2; = p.P258L on NM_014770.4) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs138992134, COSV57727895; called by muse, mutect2, varscan2
- AHCY | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs1450713730, COSV54153076; called by muse, mutect2, varscan2
- AIDA | c.252A>C p.E84D | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100388012; called by muse, mutect2, varscan2
- AIRE | c.539-1G>T p.X180_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | catalogued as COSV52393775; called by muse, mutect2, varscan2
- AIRE | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs554954634, COSV52393789; called by muse, mutect2, varscan2
- AJM1 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1317335613, COSV56032723; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKNAD1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as rs200156438, COSV100645949; called by muse, mutect2, varscan2
- AKR7A2 | c.400del p.Q134Kfs*87 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | catalogued as rs1195816856; called by mutect2, pindel, varscan2
- AKT2 | c.153del p.L52* | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as COSV100251670; called by mutect2, pindel, varscan2
- AL121899.2 | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1326232990, COSV67350443; called by muse, mutect2, varscan2
- ALDH16A1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs576632177, COSV53192917; called by muse, mutect2, varscan2
- AMOTL2 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs745559796, COSV51438505; called by muse, mutect2
- AMPD2 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs754312171, COSV56647416; called by muse, mutect2, varscan2
- AMY2A | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs760571073, COSV101340614; called by mutect2, varscan2
- AMZ2 | c.587-2A>G p.X196_splice | Splice Site (SNP) | VAF 21/76 reads (28%) | catalogued as COSV63082841; called by muse, mutect2, varscan2
- ANAPC1 | c.5202G>A p.K1734= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100594928, COSV61975722; called by muse, mutect2, varscan2
- ANK1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as rs760928262, COSV55879876; called by muse, mutect2, varscan2
- ANK2 | c.4684G>T p.V1562L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52157769; called by muse, mutect2
- ANKRD52 | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57283964; called by muse, mutect2, varscan2
- ANO10 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV52730649; called by muse, mutect2, varscan2
- ANO2 | c.2359C>T p.R787W (on ENST00000356134 / NM_001278597.3; = p.R791W on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761883684, COSV59020062; called by muse, mutect2, varscan2
- ANXA5 | c.531+2T>C p.X177_splice | Splice Site (SNP) | VAF 32/89 reads (36%) | catalogued as COSV56638789; called by muse, mutect2, varscan2
- ANXA8 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1220680586; called by muse, mutect2, varscan2
- AP1G2 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs759104775, COSV55337301, COSV55339360; called by muse, mutect2, varscan2
- APOL5 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 29/102 reads (28%) | catalogued as COSV50766795; called by muse, mutect2, varscan2
- AQR | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762110548, COSV50032787; called by muse, mutect2, varscan2
- AQR | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV50032816; called by muse, mutect2, varscan2
- ARC | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63077915, COSV63078032, COSV63078414; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 44/134 reads (33%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARFGEF3 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV52455984; called by muse, mutect2, varscan2
- ARG2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1298184141, COSV55775917; called by muse, mutect2, varscan2
- ARHGAP26 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50828320; called by muse, mutect2, varscan2
- ARHGAP28 | c.811+1G>A p.X271_splice (on ENST00000383472 / NM_001366230.1; = p.X112_splice on NM_001010000.3) | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV51636141; called by muse, mutect2, varscan2
- ARHGAP45 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1428793340, COSV57429899; called by muse, mutect2, varscan2
- ARHGAP6 | c.2450G>A p.R817H (on ENST00000337414 / NM_013427.3; = p.R614H on NM_013423.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.926); catalogued as COSV57295041; called by muse, mutect2, varscan2
- ARHGAP9 | c.617del p.P206Qfs*28 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | catalogued as COSV62724306; called by mutect2, pindel, varscan2
- ARHGEF12 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754173692, COSV63104154; called by muse, mutect2, varscan2
- ARHGEF17 | c.5809G>A p.G1937S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361560252, COSV55231905; called by muse, mutect2, varscan2
- ARHGEF4 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58121473; called by muse, mutect2, varscan2
- ARID1A | c.2666dup p.M890Hfs*46 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as rs1286891446; called by mutect2, pindel, varscan2
- ARID1B | c.6623G>A p.R2208Q | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1302430069, COSV51659324, COSV51668662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID2 | c.322del p.E108Rfs*107 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | catalogued as COSV100536762; called by mutect2, pindel, varscan2
- ARNTL | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62985867; called by muse, mutect2, varscan2
- ARNTL2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV53825308; called by muse, mutect2, varscan2
- ARRB2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.926); catalogued as COSV52617137; called by muse, mutect2, varscan2
- ASB7 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV58403642; called by muse, mutect2, varscan2
- ASPG | c.1471del p.A491Pfs*99 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV101496466; called by mutect2, pindel, varscan2
- ASPM | c.7138C>T p.H2380Y | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.579); catalogued as COSV54128727; called by muse, mutect2, varscan2
- ASPM | c.6892G>A p.A2298T | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV54128735; called by muse, mutect2, varscan2
- ASTE1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548700211, COSV53908496; called by muse, mutect2, varscan2
- ATF6B | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV64351298, COSV64351765; called by muse, mutect2, varscan2
- ATF7IP | c.2183C>A p.P728H | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV53769963; called by muse, mutect2, varscan2
- ATP10B | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs751050963, COSV58778539; called by muse, mutect2, varscan2
- ATP12A | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs570944775, COSV54515301; called by muse, mutect2, varscan2
- ATP1A3 | c.815G>A p.R272H (on ENST00000545399 / NM_001256214.2; = p.R259H on NM_152296.5) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV57487067; called by muse, mutect2, varscan2
- ATP2B2 | c.2974G>A p.V992I (on ENST00000352432; = p.V958I on NM_001683.5) | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs765963921, COSV59495098; called by muse, mutect2, varscan2
- ATP4A | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs1172272670, COSV52867481; called by muse, mutect2, varscan2
- ATP6V0B | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs772857409, COSV52543307; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1481G>A p.R494K | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV52353394, COSV52354411; called by muse, mutect2, varscan2
- ATXN7L2 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs145282300; called by muse, mutect2, varscan2
- ATXN7L3 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 48/129 reads (37%) | catalogued as COSV66988888; called by muse, mutect2, varscan2
- AUTS2 | c.660C>T p.F220= | Splice Region (SNP) | VAF 34/105 reads (32%) | catalogued as rs766569162, COSV61397410; called by muse, mutect2, varscan2
- AXL | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56567477; called by muse, mutect2, varscan2
- B3GLCT | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as rs537023333, COSV58454363; called by muse, mutect2, varscan2
- BAP1 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV56233555; called by muse, mutect2, varscan2
- BAP1 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs759448397, COSV56233567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAN | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV61256615; called by muse, mutect2, varscan2
- BCHE | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs568724445, COSV52256159; called by muse, mutect2, varscan2
- BCKDK | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs751780870, COSV54891469; called by muse, mutect2, varscan2
- BCL11B | c.2668C>T p.Q890* (on ENST00000357195 / NM_001282237.2; = p.Q819* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV61735165; called by muse, mutect2, varscan2
- BCL11B | c.1775C>T p.A592V (on ENST00000357195 / NM_001282237.2; = p.A521V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV61735182; called by muse, varscan2
- BCL11B | c.1768G>A p.E590K (on ENST00000357195 / NM_001282237.2; = p.E519K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100596026, COSV61735188; called by muse, varscan2
- BCL11B | c.1471G>A p.G491R (on ENST00000357195 / NM_001282237.2; = p.G420R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1325009281, COSV61735199; called by muse, mutect2, varscan2
- BEST3 | c.45del p.F15Lfs*32 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | catalogued as rs1184020574; called by mutect2, pindel, varscan2
- BICC1 | c.2922G>A p.W974* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV65858893; called by muse, mutect2, varscan2
- BICD1 | c.580-2A>G p.X194_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as rs1392261369, COSV55678206; called by muse, mutect2, varscan2
- BMPR1A | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs879254049, COSV64405801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMS1 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65733696; called by muse, mutect2, varscan2
- BNC2 | c.1012T>G p.L338V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV66145754; called by muse, mutect2, varscan2
- BORCS6 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); catalogued as rs760346083, COSV66505090; called by mutect2, varscan2
- BRD2 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as COSV66373061; called by muse, mutect2, varscan2
- BRWD1 | c.4321C>T p.R1441W | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs773288022, COSV60894967; called by muse, mutect2, varscan2
- BRWD1 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760394668, COSV58122627; called by muse, mutect2, varscan2
- BTBD3 | c.758A>G p.E253G | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV54778927; called by muse, mutect2
- BTBD9 | c.1624C>T p.H542Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.932); catalogued as COSV58424647; called by muse, mutect2, varscan2
- C11orf45 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs143711749, COSV57965516; called by muse, mutect2
- C12orf43 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | catalogued as rs754711835, COSV56567034; called by muse, mutect2, varscan2
- C14orf39 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1055758388, COSV58781438; called by muse, mutect2, varscan2
- C16orf70 | c.1230dup p.R411Qfs*4 | Frame Shift Ins (INS) | VAF 46/136 reads (34%) | catalogued as rs539297455; called by mutect2, varscan2
- C17orf75 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs767983788, COSV56752690; called by muse, mutect2, varscan2
- C2orf42 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52449936; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs762988845; called by mutect2, varscan2
- CABIN1 | c.2645C>T p.T882M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs41310246; called by muse, mutect2, varscan2
- CABP5 | c.433del p.R145Gfs*24 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | catalogued as rs769959570, COSV99506527; called by mutect2, pindel, varscan2
- CACNA1C | c.4624C>T p.R1542C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59697521; called by muse, mutect2, varscan2
- CACNA1D | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55444993; called by muse, mutect2, varscan2
- CACNA1G | c.1296C>A p.C432* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV61725465; called by muse, mutect2
- CACNA1H | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772154386, COSV61988665; called by muse, mutect2, varscan2
- CACNA1H | c.6545G>A p.R2182H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs200724225, COSV52354190; called by muse, mutect2, varscan2
- CACNA1S | c.5495T>C p.L1832P | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62938905; called by muse, mutect2, varscan2
- CAD | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV53026136; called by muse, mutect2, varscan2
- CADPS2 | c.1847A>G p.Q616R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV57360696; called by muse, mutect2, varscan2
- CAMK2D | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); catalogued as COSV56429452; called by muse, mutect2, varscan2
- CAMSAP2 | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV52669701; called by muse, mutect2, varscan2
- CAPG | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55707250; called by muse, mutect2, varscan2
- CAPN1 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs763471308, COSV54198268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN15 | c.760dup p.Q254Pfs*8 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs1334169568; called by mutect2, varscan2
- CAPN6 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60694739; called by muse, mutect2
- CAPSL | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV68437941; called by muse, mutect2, varscan2
- CARMIL3 | c.4075C>T p.R1359W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs139310553; called by mutect2, varscan2
- CASP5 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52828233; called by muse, mutect2, varscan2
- CATSPERB | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs145060222; called by muse, mutect2, varscan2
- CBFA2T2 | c.1321del p.T441Qfs*5 | Frame Shift Del (DEL) | VAF 38/154 reads (25%) | catalogued as COSV100656585; called by mutect2, pindel, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | catalogued as rs780649799; called by mutect2, varscan2
- CBX7 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs764292269, COSV53358907; called by muse, mutect2, varscan2
- CCDC105 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs545556924, COSV52963784; called by muse, mutect2
- CCDC114 | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs200855924, COSV59556337; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 21/41 reads (51%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC30 | c.1946del p.N649Ifs*12 (on ENST00000340612; = p.N606Ifs*12 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | catalogued as rs762111867; called by mutect2, pindel, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC80 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs749903251, COSV52816389; called by muse, mutect2, varscan2
- CCDC87 | c.1441dup p.M481Nfs*4 | Frame Shift Ins (INS) | VAF 55/188 reads (29%) | catalogued as rs1251984014; called by mutect2, pindel, varscan2
- CCDC92 | c.652T>C p.F218L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53019538; called by muse, mutect2, varscan2
- CCKBR | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as rs201626406, COSV100582997, COSV58100822; called by muse, mutect2, varscan2
- CCL27 | c.204-1G>T p.X68_splice | Splice Site (SNP) | VAF 39/128 reads (30%) | catalogued as COSV99426382; called by muse, mutect2, varscan2
- CCNE1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 106/345 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs1225502237, COSV52904173; called by muse, mutect2, varscan2
- CCP110 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66816886; called by muse, mutect2, varscan2
- CDC42BPB | c.4042G>A p.V1348M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.14); catalogued as rs746522635, COSV63474726; called by muse, mutect2, varscan2
- CDC42BPB | c.177T>C p.A59= | Splice Region (SNP) | VAF 5/25 reads (20%) | catalogued as COSV63474729; called by muse, mutect2
- CDC5L | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as rs148664123; called by muse, mutect2, varscan2
- CDCA2 | c.2965A>G p.T989A | Missense Mutation (SNP) | VAF 148/291 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1370810500, COSV57945623; called by muse, mutect2, varscan2
- CDCA7L | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62258881; called by muse, mutect2, varscan2
- CDCP2 | c.1159del p.E387Rfs*23 | Frame Shift Del (DEL) | VAF 51/118 reads (43%) | catalogued as rs1354858247; called by mutect2, pindel, varscan2
- CDH11 | c.1619A>T p.N540I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV51759778; called by muse, mutect2, varscan2
- CDH12 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66400967; called by muse, mutect2, varscan2
- CDH13 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 28/101 reads (28%) | catalogued as rs751441653, COSV51813549, COSV99224247; called by muse, mutect2, varscan2
- CDH8 | c.1539C>A p.V513= | Splice Region (SNP) | VAF 17/53 reads (32%) | catalogued as COSV54863148; called by muse, varscan2
- CDHR1 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV60561705; called by muse, mutect2, varscan2
- CDK12 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70999516, COSV71000400; called by muse, mutect2, varscan2
- CDT1 | c.1558T>C p.Y520H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56348086; called by muse, mutect2
- CEBPZ | c.2683A>G p.N895D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1447497101, COSV52206031; called by muse, mutect2, varscan2
- CELSR2 | c.6080C>T p.S2027F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54770434; called by muse, mutect2, varscan2
- CELSR3 | c.5584C>T p.R1862W | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs748113150, COSV50851827; called by muse, mutect2, varscan2
- CENPJ | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs763694655, COSV67883357; called by muse, mutect2, varscan2
- CEP112 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs774877438, COSV67138624; called by muse, mutect2, varscan2
- CES5A | c.515T>C p.V172A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV51865734; called by muse, mutect2, varscan2
- CFAP57 | c.991A>G p.N331D | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV65264287; called by muse, varscan2
- CFAP65 | c.3511C>A p.L1171I | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58560317; called by muse, mutect2, varscan2
- CFAP77 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs746755413, COSV58010313; called by muse, mutect2, varscan2
- CHAC1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs556102949, COSV71436040; called by muse, mutect2, varscan2
- CHD5 | c.4037G>A p.R1346H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52413070; called by muse, mutect2, varscan2
- CHD7 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1355349547, CD126719, COSV71109590; called by muse, mutect2, varscan2
- CHD7 | c.8213C>T p.T2738M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs761409446, COSV71109597; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHDH | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs574370935, COSV55445006; called by muse, mutect2, varscan2
- CHKA | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV55839651; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST6 | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV59999926; called by muse, mutect2, varscan2
- CHSY3 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781436925, COSV59276606; called by muse, mutect2, varscan2
- CIB3 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV54166038; called by muse, mutect2, varscan2
- CIITA | c.2377C>A p.L793M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60856502, COSV60857167; called by muse, mutect2, varscan2
- CKAP4 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1464031948, COSV65172407; called by muse, mutect2, varscan2
- CKAP5 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs377474304; called by muse, mutect2, varscan2
- CKB | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1383661662, COSV62379476; called by muse, mutect2, varscan2
- CLCA4 | c.2291C>T p.T764I | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs1426524473, COSV65283228; called by muse, mutect2, varscan2
- CLCNKB | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.861); catalogued as rs1307215192, CM138093, COSV65160360; called by muse, mutect2, varscan2
- CLDN5 | c.59del p.G20Vfs*2 (on ENST00000618236 / NM_001363066.2; = p.G105Vfs*2 on NM_003277.4) | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs768198935; called by mutect2, varscan2
- CLEC7A | c.679G>A p.V227I (on ENST00000304084 / NM_197947.3; = p.V181I on NM_022570.5) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53722146; called by muse, mutect2, varscan2
- CLIP1 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56800997; called by muse, mutect2, varscan2
- CLIP3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs553572365, COSV62111734; called by muse, mutect2, varscan2
- CLPB | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.644); catalogued as COSV53629357; called by muse, mutect2, varscan2
- CLPX | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.384); catalogued as rs769874820, COSV55644217; called by muse, mutect2, varscan2
- CLSTN1 | c.1844C>T p.T615M (on ENST00000377298 / NM_001009566.3; = p.T605M on NM_014944.4) | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424803630, COSV63647855; called by muse, mutect2, varscan2
- CLSTN2 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV71720505; called by muse, mutect2, varscan2
- CMYA5 | c.5069C>T p.A1690V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs768487853, COSV71405565; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs374805044; called by mutect2, varscan2
- COG5 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs755030238, COSV51744556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A1 | c.3015A>T p.E1005D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62181436; called by muse, mutect2, varscan2
- COL12A1 | c.9002G>A p.G3001D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59394651, COSV59404398; called by muse, mutect2
- COL1A1 | c.3247G>A p.A1083T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs372029024; called by muse, mutect2
- COL22A1 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.24); catalogued as rs202129460; called by muse, mutect2, varscan2
- COL27A1 | c.3553C>T p.R1185W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs183678867, COSV61924456; called by muse, mutect2, varscan2
- COL2A1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1409377649, COSV61528181; called by muse, mutect2, varscan2
- COL4A2 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.121); catalogued as rs779357792, COSV64627571; called by muse, mutect2, varscan2
- COL4A4 | c.2464G>T p.G822C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631505; called by muse, mutect2, varscan2
- COL6A2 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs1174497288, COSV52424993; called by muse, mutect2, varscan2
- COL9A3 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780313887, COSV58984510; called by muse, mutect2, varscan2
- COX4I1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs772180664, COSV53665685; called by muse, mutect2, varscan2
- CPAMD8 | c.2168C>T p.P723L (on ENST00000651564; = p.P676L on NM_015692.5) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs775789814, COSV52232882; called by muse, mutect2, varscan2
- CPAMD8 | c.266G>A p.R89H (on ENST00000651564; = p.R42H on NM_015692.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs368347732; called by muse, mutect2, varscan2
- CPN1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs761479872, COSV64942215; called by muse, mutect2, varscan2
- CPO | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as COSV55939573; called by muse, mutect2, varscan2
- CPVL | c.794del p.K265Sfs*11 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs1562753933; called by mutect2, pindel, varscan2
- CRAMP1 | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV51961587; called by muse, mutect2, varscan2
- CREB3 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV59206891; called by muse, mutect2, varscan2
- CREBBP | c.7030C>T p.R2344W | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1299672210, COSV52121347; called by muse, mutect2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 48/128 reads (38%) | catalogued as rs769538822; called by mutect2, varscan2
- CSHL1 | c.108del p.F36Lfs*23 | Frame Shift Del (DEL) | VAF 43/167 reads (26%) | catalogued as COSV51988036; called by mutect2, pindel, varscan2
- CSMD1 | c.7274A>C p.K2425T (on ENST00000520002; = p.K2424T on NM_033225.6) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV59314561; called by mutect2, varscan2
- CSMD1 | c.1919C>T p.A640V (on ENST00000520002; = p.A639V on NM_033225.6) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs183309351, COSV59314590; called by muse, mutect2, varscan2
- CSNK1G1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs765536461, COSV57308885; called by muse, mutect2, varscan2
- CSTF2T | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100484067, COSV58657022; called by muse, mutect2, varscan2
- CTCFL | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs144712440; called by muse, mutect2, varscan2
- CTRC | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 38/606 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391825093, COSV65621413; called by muse, mutect2
- CTSA | c.990dup p.C331Lfs*56 | Frame Shift Ins (INS) | VAF 26/68 reads (38%) | catalogued as rs758642867; called by mutect2, varscan2
- CTSB | c.103A>G p.N35D | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61540647; called by muse, mutect2, varscan2
- CUBN | c.9442C>T p.R3148W | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs749089689, COSV64713157; ClinVar: uncertain significance; called by muse, varscan2
- CUEDC1 | c.332del p.P111Rfs*136 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | catalogued as COSV100804649, COSV64227288; called by mutect2, pindel, varscan2
- CUL5 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101263752, COSV67608747; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs745836350; called by mutect2, varscan2
- CYP2D6 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs574629217, COSV62243796; called by muse, mutect2, varscan2
- CYP8B1 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs1033043019, COSV60226217; called by muse, mutect2, varscan2
- CYYR1 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV54831208; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs751187768; called by mutect2, varscan2
- DALRD3 | c.519G>T p.Q173H (on ENST00000341949 / NM_001009996.3; = p.Q6H on NM_018114.5) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as COSV58244805; called by muse, mutect2, varscan2
- DBR1 | c.1509G>T p.E503D | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53429591; called by muse, mutect2
- DCAF8L1 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV71595247, COSV71595549; called by muse, mutect2
- DCTN1 | c.2400G>T p.K800N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62620343; called by muse, mutect2, varscan2
- DDR1 | c.774G>T p.W258C | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61320878; called by muse, mutect2, varscan2
- DDX18 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs763934906, COSV54306345; called by muse, mutect2, varscan2
- DDX19A | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56359659; called by muse, mutect2, varscan2
- DDX3X | c.922C>T p.Q308* (on ENST00000399959; = p.Q309* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 65/177 reads (37%) | catalogued as COSV67863459; called by muse, mutect2, varscan2
- DDX41 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs1284585050, COSV57903160; called by muse, mutect2, varscan2
- DDX54 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV100013917, COSV58373149; called by muse, mutect2, varscan2
- DEPDC1B | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs143548430; called by muse, mutect2, varscan2
- DHRS12 | c.686C>A p.P229H (on ENST00000444610 / NM_001377930.1; = p.P180H on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54471127; called by muse, mutect2, varscan2
- DHX30 | c.3364G>A p.D1122N (on ENST00000445061 / NM_138615.3; = p.D1083N on NM_014966.3) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs763406572, COSV53137052; called by muse, mutect2, varscan2
- DIDO1 | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56620013; called by muse, mutect2, varscan2
- DIS3L2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs752699253, COSV56053158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP2 | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 77/580 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs370777054; called by muse, mutect2, varscan2
- DLC1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs11990333; called by muse, mutect2, varscan2
- DLG5 | c.3812C>T p.A1271V | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as rs373592990, COSV64947736; called by muse, mutect2, varscan2
- DLGAP1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs200970393, COSV59800019; called by muse, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH11 | c.9038C>T p.A3013V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs553655709, COSV60940381; called by muse, mutect2, varscan2
- DNAH14 | c.747A>T p.E249D (on ENST00000445597; = p.E72D on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.131); catalogued as COSV100835827; called by muse, mutect2, varscan2
- DNAH17 | c.5362C>T p.R1788W | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748651545, COSV67759930; called by muse, mutect2
- DNAH5 | c.877del p.R293Dfs*12 | Frame Shift Del (DEL) | VAF 68/258 reads (26%) | catalogued as COSV54201852; called by mutect2, pindel, varscan2
- DNAH8 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs749933430, COSV59433019, COSV59441381; called by mutect2, varscan2
- DNAH9 | c.9796T>C p.C3266R | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52346575; called by muse, mutect2, varscan2
- DNAJC11 | c.731A>G p.Q244R | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs755185368, COSV53786221; called by muse, mutect2, varscan2
- DNAJC17 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs751041536, COSV55024811; called by muse, mutect2, varscan2
- DNASE1L1 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV50010248; called by muse, mutect2, varscan2
- DNMT3A | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53037374, COSV99258021; called by muse, mutect2, varscan2
- DNTT | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1437175894, COSV64522938; called by muse, mutect2, varscan2
- DOCK3 | c.5611C>A p.P1871T | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56517689; called by muse, mutect2, varscan2
- DOCK6 | c.5543G>A p.R1848H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs201858507; called by muse, mutect2, varscan2
- DOK6 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1314752927, COSV66930095; called by muse, mutect2, varscan2
- DOP1A | c.6779C>T p.A2260V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV52709487; called by muse, mutect2, varscan2
- DOP1B | c.6689C>T p.P2230L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs1391932785, COSV67690726; called by muse, mutect2, varscan2
- DPP3 | c.1612G>A p.V538M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1346296209, COSV64756572; called by muse, mutect2, varscan2
- DPYD | c.1525-2A>G p.X509_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as COSV64595976; called by muse, mutect2, varscan2
- DPYSL2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 76/167 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.697); catalogued as rs759388658, COSV60783146; called by muse, mutect2, varscan2
- DUS3L | c.934del p.L312Sfs*20 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as rs1282039483; called by mutect2, pindel, varscan2
- DUS4L-BCAP29 | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.091); catalogued as COSV50051394; called by muse, mutect2, varscan2
- DVL1 | c.1405A>G p.K469E (on ENST00000378888 / NM_001330311.2; = p.K444E on NM_004421.3) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59563079; called by muse, mutect2, varscan2
- DVL2 | c.2174T>C p.M725T | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs767490193, COSV50035557; called by muse, mutect2, varscan2
- DVL3 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs935183487, COSV53047849; called by muse, mutect2, varscan2
- DYNC1H1 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as rs988847052, COSV64136427; called by muse, mutect2, varscan2
- DYNC2H1 | c.4072C>T p.R1358C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs771671546, COSV62092633; called by muse, mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- DYSF | c.6125G>A p.R2042H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs927657254, COSV50303360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs576293914, COSV61265398; called by muse, varscan2
- DZIP1L | c.1595A>G p.Q532R | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.297); catalogued as COSV59520363; called by muse, mutect2, varscan2
- EBNA1BP2 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 85/424 reads (20%) | catalogued as rs767272546, COSV52539942; called by muse, mutect2, varscan2
- ECI1 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242066396, COSV57038686; called by muse, mutect2, varscan2
- ECM2 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1367908869, COSV60740207; called by muse, mutect2, varscan2
- EDAR | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs121908456, CM081577, COSV51502165; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295del p.X99_splice | Splice Site (DEL) | VAF 10/50 reads (20%) | catalogued as rs756314578; called by mutect2, varscan2
- EEF1AKMT4 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955462; called by muse, mutect2, varscan2
- EEF2K | c.586del p.E196Rfs*22 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as rs1567276794; called by mutect2, pindel, varscan2
- EHBP1L1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); catalogued as rs375941599; called by muse, mutect2, varscan2
- EHD2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV54408047; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 58/115 reads (50%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3A | c.2806C>T p.R936W | Missense Mutation (SNP) | VAF 107/331 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs762013834, COSV64961211; called by muse, mutect2, varscan2
- EIF3A | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs755084308, COSV64961215; called by muse, mutect2, varscan2
- EIF3G | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs150270880; called by muse, mutect2, varscan2
- EIF4G1 | c.2680C>T p.R894C (on ENST00000346169 / NM_198241.3; = p.R699C on NM_004953.5) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs1332119177, COSV59989105; called by muse, mutect2, varscan2
- EIF4G1 | c.4323G>T p.E1441D (on ENST00000346169 / NM_198241.3; = p.E1246D on NM_004953.5) | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV59990545; called by muse, mutect2, varscan2
- EIF4G3 | c.4432G>A p.D1478N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs763894341, COSV51680598; called by muse, mutect2, varscan2
- ELANE | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs569608929, CM077849, COSV55047933; called by muse, mutect2
- ELAVL1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV60965814; called by muse, mutect2, varscan2
- ELAVL4 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs199932597, COSV100836492, COSV63915579; called by muse, mutect2, varscan2
- ELOA | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs201928604, COSV69310075, COSV69310207; called by muse, mutect2, varscan2
- ELOA | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV69310080; called by muse, varscan2
- ELOVL7 | c.279A>G p.I93M | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs771365279, COSV70917944; called by muse, mutect2, varscan2
- EMILIN1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753284656, COSV100980199, COSV66694626; called by muse, mutect2, varscan2
- ENC1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV56629489; called by muse, mutect2, varscan2
- EP400 | c.2827+1G>A p.X943_splice | Splice Site (SNP) | VAF 42/110 reads (38%) | catalogued as COSV57770335; called by muse, mutect2, varscan2
- EP400 | c.3560G>A p.R1187H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as rs773523648, COSV57762375; called by muse, mutect2, varscan2
- EP400 | c.4400G>A p.R1467Q | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV57769992; called by muse, mutect2, varscan2
- EPPIN | c.278G>T p.W93L | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60548550; called by muse, mutect2
- EPS8 | c.2194A>G p.T732A | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55530016; called by muse, mutect2
- ERICH1 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV100032162; called by muse, mutect2, varscan2
- ESPNL | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58032314; called by muse, mutect2, varscan2
- ESR1 | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.58); catalogued as rs778116774, COSV52785565; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 46/107 reads (43%) | catalogued as rs775950025; called by mutect2, varscan2
- ETFDH | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57014764; called by muse, mutect2, varscan2
- ETV6 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs111871763; called by muse, mutect2, varscan2
- EVI5L | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV54485340; called by muse, mutect2
- EVPL | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV56910125; called by muse, mutect2, varscan2
- EXD3 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138566172, COSV59806648; called by muse, mutect2, varscan2
- EXOSC10 | c.1437+2T>C p.X479_splice | Splice Site (SNP) | VAF 14/67 reads (21%) | catalogued as rs769651237, COSV58665165; called by muse, mutect2, varscan2
- EYA1 | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); catalogued as COSV58161383; called by muse, mutect2, varscan2
- EZH2 | c.2133del p.F711Lfs*24 (on ENST00000460911 / NM_001203247.2; = p.F716Lfs*24 on NM_004456.5) | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | catalogued as COSV104412042; called by mutect2, pindel, varscan2
- FAAP100 | c.1495A>G p.S499G | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV100585565, COSV59885054; called by muse, mutect2, varscan2
- FAM111B | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs144133192; called by muse, mutect2, varscan2
- FAM120B | c.1511C>A p.S504Y | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV53003348; called by muse, varscan2
- FAM131A | c.512T>C p.F171S (on ENST00000310585; = p.F202S on NM_144635.5) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV55600746; called by muse, mutect2, varscan2
- FAM13B | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs775718846, COSV50365761; called by muse, mutect2, varscan2
- FAM13B | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV50365801; called by muse, mutect2, varscan2
- FAM151B | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV56472796; called by muse, mutect2, varscan2
- FAM160B2 | c.1774del p.H592Mfs*30 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs760552753; called by mutect2, pindel, varscan2
- FAM234B | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52194340; called by muse, mutect2, varscan2
- FAM241B | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV64768230; called by muse, mutect2, varscan2
- FAM53A | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs566928749, COSV57401280; called by muse, mutect2, varscan2
- FAM83E | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52375718; called by muse, mutect2
- FAM91A1 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs771545014, COSV58236123, COSV58236785; called by muse, mutect2, varscan2
- FAT4 | c.10055A>C p.K3352T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as rs1386048788, COSV58681601, COSV58686093; called by muse, mutect2, varscan2
- FAT4 | c.12901G>A p.V4301I | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58681620; called by muse, mutect2
- FCGBP | c.4306C>T p.P1436S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.493); catalogued as COSV55435380; called by muse, mutect2, varscan2
- FCGRT | c.320del p.G107Efs*29 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1568698688; called by mutect2, pindel, varscan2
- FDPS | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV52739297; called by muse, mutect2
- FEN1 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs761723999, COSV57250749, COSV99952957; called by muse, mutect2, varscan2
- FFAR3 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100588106; called by muse, mutect2
- FGF6 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780465055, COSV57403803; called by muse, mutect2
- FGFR2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs199575491, COSV60645597; called by muse, mutect2, varscan2
- FGFR4 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770012793, COSV52802832; called by muse, mutect2, varscan2
- FJX1 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.463); catalogued as rs777561243, COSV58552952; called by muse, mutect2
- FLT4 | c.1267dup p.Q423Pfs*4 | Frame Shift Ins (INS) | VAF 28/103 reads (27%) | catalogued as rs750808726; called by mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as COSV56098414; called by mutect2, varscan2
- FMNL3 | c.3022C>T p.R1008C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs545464076, COSV53300547; called by muse, mutect2, varscan2
- FOXO1 | c.1493T>C p.M498T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV65426486; called by muse, mutect2, varscan2
- FRMD1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs186693438, COSV51961532; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMD8 | c.551A>C p.Q184P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.14); catalogued as COSV58212377; called by muse, mutect2, varscan2
- FRY | c.5888C>T p.P1963L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs774579512, COSV100969338, COSV66569174; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1348158626; called by mutect2, varscan2
- FTMT | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58419681; called by muse, mutect2, varscan2
- FYCO1 | c.1788G>T p.Q596H | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56115478; called by muse, mutect2, varscan2
- FZR1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV58050143; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GABARAPL1 | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV56770763; called by muse, mutect2, varscan2
- GABRB3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1197311612, COSV54661471, COSV54667048; called by muse, mutect2, varscan2
- GABRB3 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347499222, COSV54661500, COSV54683742; called by muse, mutect2, varscan2
- GABRG2 | c.1247C>A p.P416H (on ENST00000361925 / NM_001375343.1; = p.P376H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100729767, COSV62717547; called by muse, mutect2, varscan2
- GABRR2 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs559529251, COSV68764476; called by muse, mutect2, varscan2
- GAK | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV58504203; called by muse, mutect2
- GALNT12 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs756339026, COSV66662601; called by muse, mutect2, varscan2
- GAN | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV73720861; called by muse, mutect2, varscan2
- GARNL3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs764762853, COSV59223641; called by muse, mutect2, varscan2
- GBE1 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs774619760, CM128774, COSV70098724, COSV70101993; called by muse, mutect2, varscan2
- GCM2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65275460, COSV65275653; called by muse, mutect2, varscan2
- GCN1 | c.3632G>A p.R1211Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.167); catalogued as rs372258623; called by muse, mutect2, varscan2
- GDI2 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1354631339, COSV66334622; called by muse, mutect2, varscan2
- GET4 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56212788; called by muse, mutect2, varscan2
- GFI1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as rs770564130, COSV54042460; called by mutect2, varscan2
- GIGYF1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770263326, COSV51941191; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP8 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs200505163; called by muse, mutect2, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GJA8 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs782773520, COSV53788628; called by muse, mutect2, varscan2
- GJA8 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs372038463; called by muse, mutect2, varscan2
- GK2 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV62626645; called by muse, mutect2, varscan2
- GLI3 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67887839; called by muse, mutect2, varscan2
- GMIP | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1213104382, COSV52554047; called by muse, mutect2, varscan2
- GNAI3 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV63983646; called by muse, mutect2, varscan2
- GNAL | c.1078C>T p.R360C (on ENST00000269162 / NM_001142339.3; = p.R437C on NM_182978.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1297200293, COSV52325900, COSV52326521; called by muse, mutect2, varscan2
- GNAS | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs747005037, COSV58333403, COSV58347402; called by muse, mutect2, varscan2
- GNAZ | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV50737743; called by muse, mutect2, varscan2
- GPR149 | c.1049T>G p.L350R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67666984; called by muse, mutect2, varscan2
- GPR6 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51571736; called by muse, mutect2, varscan2
- GREM2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as COSV58950136; called by muse, mutect2, varscan2
- GRIA3 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 59/76 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV99988772; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs780055449, COSV66138863; called by muse, mutect2, varscan2
- GRIN3A | c.1610G>T p.C537F | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62452935; called by muse, mutect2, varscan2
- GRIP2 | c.3353G>A p.R1118H (on ENST00000619221; = p.R1021H on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772124501, COSV56121048; called by muse, mutect2, varscan2
- GRM7 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); catalogued as rs74549759, COSV63137782; called by muse, mutect2, varscan2
- GRXCR1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.996); catalogued as rs376573747; called by muse, mutect2, varscan2
- GSDME | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61651500; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 24/103 reads (23%) | catalogued as rs754199513; called by mutect2, varscan2
- GSTM4 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV58694471; called by muse, mutect2, varscan2
- GSTM5 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV56657718; called by muse, mutect2, varscan2
- GTF2A1 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53336936; called by muse, mutect2, varscan2
- GTF2E1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs140000454, COSV52204033; called by muse, mutect2, varscan2
- GTF2H4 | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV52558643; called by muse, mutect2, varscan2
- GTF2H4 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); catalogued as rs762153930, COSV52558664; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2269A>G p.T757A (on ENST00000265755 / NM_016328.3; = p.T742A on NM_005685.4) | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56086177; called by muse, mutect2, varscan2
- GTF3C2 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV53126232; called by muse, mutect2, varscan2
- GTF3C2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs780337619, COSV53126244; called by muse, mutect2, varscan2
- GUCA1C | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV51718723; called by muse, mutect2, varscan2
- GYS1 | c.1896G>T p.Q632H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.663); catalogued as COSV54402492; called by mutect2, varscan2
- GZMM | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 23/51 reads (45%) | catalogued as COSV52742121; called by muse, mutect2, varscan2
- HACD1 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV63516308; called by muse, mutect2
- HCRTR2 | c.32dup p.C12Lfs*12 | Frame Shift Ins (INS) | VAF 45/157 reads (29%) | catalogued as rs755844571; called by mutect2, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs57105282; called by mutect2, varscan2
- HELQ | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55024987; called by muse, mutect2, varscan2
- HESX1 | c.533del p.N178Ifs*10 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | catalogued as rs759180706; called by mutect2, varscan2
- HFM1 | c.3759A>C p.E1253D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.037); catalogued as COSV54026128; called by muse, varscan2
- HGS | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs147280688; called by muse, mutect2, varscan2
- HHIPL1 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58090140; called by muse, mutect2, varscan2
- HIF1A | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60189023; called by muse, mutect2, varscan2
- HIGD1A | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV58414869; called by muse, mutect2, varscan2
- HINFP | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs765481086, COSV63431897; called by muse, mutect2, varscan2
- HIPK2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.823); catalogued as COSV61227132; called by muse, varscan2
- HK1 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV53857104; called by muse, mutect2, varscan2
- HK1 | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as COSV53857144; called by muse, mutect2, varscan2
- HMBOX1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs528996837, COSV55067741, COSV55068328; called by muse, mutect2, varscan2
- HMCN1 | c.13969G>A p.E4657K | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1183965155, COSV54890148; called by muse, mutect2, varscan2
- HNRNPCL1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs781198391, COSV58613119; called by muse, mutect2, varscan2
- HNRNPL | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs1228792246, COSV55492313; called by muse, mutect2
- HNRNPR | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV56421119; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1519A>G p.S507G | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV57132032; called by muse, mutect2, varscan2
- HOOK2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1455714684, COSV53402078; called by muse, mutect2, varscan2
- HOXA3 | c.359del p.P120Rfs*40 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as COSV57828997; called by mutect2, pindel
- HPCAL1 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV57145734; called by muse, mutect2, varscan2
- HRC | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV53256065; called by muse, mutect2, varscan2
- HS3ST6 | c.493del p.R165Afs*12 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs1205755250, COSV99562619, COSV99562884; called by mutect2, pindel
- HSD17B4 | c.730G>A p.A244T (on ENST00000414835 / NM_001199291.3; = p.A219T on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV56335210; called by muse, mutect2, varscan2
- HSPA12A | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs199760082; called by muse, mutect2, varscan2
- HSPA14 | c.458dup p.N153Kfs*8 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs775839750; called by mutect2, varscan2
- HYLS1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as COSV54989897; called by muse, mutect2, varscan2
- HYOU1 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs781881422, COSV68215613; called by muse, mutect2, varscan2
- IBTK | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60392482; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs747841314; called by mutect2, varscan2
- IFFO1 | c.1264C>A p.L422M (on ENST00000396840 / NM_001330324.2; = p.L425M on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60737399; called by muse, mutect2, varscan2
- IFT122 | c.521dup p.S175Lfs*26 (on ENST00000348417 / NM_052989.3; = p.S175Lfs*18 on NM_018262.4) | Frame Shift Ins (INS) | VAF 48/248 reads (19%) | catalogued as rs751753419; called by mutect2, pindel, varscan2
- IGF2R | c.4276G>A p.A1426T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1271906368, COSV63626916; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGSF1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs780847353, COSV63837170; called by muse, mutect2, varscan2
- IL27RA | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.212); catalogued as rs372977633; called by muse, mutect2, varscan2
- IL4I1 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as COSV62009624; called by muse, mutect2, varscan2
- IMPG2 | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51977228; called by muse, mutect2, varscan2
- INHBC | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV59004983; called by muse, varscan2
- INO80 | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62737676; called by muse, mutect2, varscan2
- INPP5A | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.2); catalogued as rs150116834; called by muse, mutect2, varscan2
- INPP5B | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs749232995, COSV65958108; called by muse, mutect2, varscan2
- IP6K1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.759); catalogued as rs754376936, COSV57695380; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1561359523; called by mutect2, varscan2
- IPO13 | c.2434C>T p.R812* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as rs751137210, COSV54837007; called by muse, mutect2, varscan2
- ITM2C | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs150758684; called by muse, mutect2, varscan2
- JADE3 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 23/36 reads (64%) | catalogued as COSV54466078; called by muse, mutect2, varscan2
- JAG2 | c.3319C>T p.R1107C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413207667, COSV59308391; called by muse, mutect2, varscan2
- JAK1 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53806640, COSV99605223; called by muse, mutect2, varscan2
- JAK3 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV71685985; called by muse, mutect2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs1226801045; called by mutect2, varscan2
- JPH4 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1361876159, COSV58114022; called by muse, mutect2
- JPH4 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62508656; called by muse, mutect2
- KATNAL2 | c.1070C>T p.S357L (on ENST00000356157 / NM_001353899.1; = p.S285L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55297891; called by muse, mutect2, varscan2
- KATNB1 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as rs552380941, COSV65550014; called by muse, mutect2, varscan2
- KCNC1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1167748453, COSV56393797; called by muse, mutect2, varscan2
- KCNF1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs1370331713, COSV54463030; called by muse, mutect2, varscan2
- KCNH4 | c.2397del p.R800Gfs*28 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs778022334; called by mutect2, pindel, varscan2
- KCNK10 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as rs767566398, COSV56643622; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs766469179, COSV56415804; called by mutect2, pindel, varscan2
- KCTD10 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as COSV57326660; called by muse, mutect2, varscan2
- KDR | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs758102038, COSV55757419, COSV55763403; called by mutect2, varscan2
- KHNYN | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52160088; called by muse, mutect2, varscan2
- KIAA1217 | c.4229A>G p.D1410G | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV56815794; called by muse, mutect2, varscan2
- KIF15 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.771); catalogued as rs145837852; called by muse, mutect2, varscan2
- KIF16B | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757038722, COSV61705308; called by muse, mutect2, varscan2
- KIF16B | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.063); catalogued as rs144734414; called by muse, mutect2, varscan2
- KIF17 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs140125368; called by muse, mutect2
- KIF18B | c.2386C>T p.R796C (on ENST00000593135 / NM_001265577.2; = p.R808C on NM_001264573.2) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs748052207, COSV59272489; called by muse, mutect2
- KIF21B | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 150/313 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV59756620; called by muse, mutect2, varscan2
- KIF26B | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63640418; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KIRREL1 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs754743295, COSV63286139; called by muse, mutect2, varscan2
- KLC1 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781074625, COSV99871064; called by muse, mutect2, varscan2
- KLC4 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765504507, COSV52435237; called by muse, mutect2, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 43/130 reads (33%) | catalogued as rs1227078726; called by mutect2, pindel, varscan2
- KLHL40 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV55134169; called by muse, mutect2, varscan2
- KLHL41 | c.215del p.K72Rfs*3 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | catalogued as COSV52930337; called by mutect2, varscan2
- KLK15 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs758236941, COSV56826659; called by muse, mutect2, varscan2
- KLK5 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs758457993, COSV60450120; called by muse, mutect2, varscan2
- KLRG2 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.103); catalogued as rs181619768; called by muse, mutect2, varscan2
- KMT2A | c.10871C>T p.A3624V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63285073; called by muse, mutect2, varscan2
- KMT2B | c.4175C>A p.P1392Q | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV55860100; called by muse, mutect2, varscan2
- KREMEN2 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53555889; called by muse, mutect2, varscan2
- KRT23 | c.809T>C p.M270T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV52927558; called by muse, mutect2
- KRTAP17-1 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 30/66 reads (45%) | PolyPhen probably damaging (0.991); catalogued as COSV61972130; called by muse, mutect2, varscan2
- LAMB3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs752418863, COSV61916511; called by muse, mutect2, varscan2
- LEMD1 | c.110del p.K37Sfs*2 | Frame Shift Del (DEL) | VAF 31/148 reads (21%) | catalogued as rs774476336, COSV65671631; called by mutect2, pindel, varscan2
- LHFPL3 | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs768551631, COSV67810338; called by muse, mutect2, varscan2
- LIN7B | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55521437; called by muse, mutect2, varscan2
- LINGO4 | c.931T>C p.C311R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV63214373; called by muse, mutect2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | catalogued as rs748712732; called by mutect2, varscan2
- LONRF1 | c.1656A>T p.K552N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV68036657; called by muse, mutect2, varscan2
- LONRF3 | c.1706C>A p.P569H (on ENST00000371628 / NM_001031855.3; = p.P528H on NM_024778.5) | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59151724; called by muse, mutect2
- LOXL2 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs769934464, COSV66691269; called by muse, mutect2, varscan2
- LPIN1 | c.2370C>A p.N790K | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs755286469, COSV56764789; called by muse, mutect2, varscan2
- LPP | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs201370939, COSV57088218; called by muse, mutect2, varscan2
- LRIG1 | c.1493T>C p.I498T | Missense Mutation (SNP) | VAF 79/273 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.145); catalogued as rs1268223228, COSV56239369; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 37/157 reads (24%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP1B | c.1715T>C p.F572S | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67210841; called by muse, mutect2, varscan2
- LRRC32 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52632663; called by muse, mutect2, varscan2
- LRRC36 | c.1718G>A p.C573Y | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV52079340; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC8E | c.1684A>G p.R562G | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV60717802; called by muse, mutect2, varscan2
- LRRFIP1 | c.2305C>A p.L769I (on ENST00000392000 / NM_001137552.2; = p.L745I on NM_004735.4) | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV55251263; called by muse, mutect2, varscan2
- LY6G5B | c.57G>T p.K19N | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65507847; called by muse, mutect2, varscan2
- LYZL2 | c.209G>A p.R70H (on ENST00000375318; = p.R24H on NM_183058.3) | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs375255325, COSV100940618; called by muse, mutect2, varscan2
- LZTS1 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748585946, COSV56116618, COSV99743317; called by muse, mutect2, varscan2
- MAGED2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as rs752150960, COSV54497581; called by muse, mutect2, varscan2
- MAGEL2 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.973); catalogued as rs755699846, COSV58566777, COSV58568348; called by muse, mutect2, varscan2
- MAMDC4 | c.1337C>A p.P446H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs1172507851, COSV56032728, COSV56034970; called by muse, mutect2, varscan2
- MAMLD1 | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 182/254 reads (72%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV53374238; called by muse, mutect2, varscan2
- MAN1C1 | c.1296dup p.L433Afs*67 | Frame Shift Ins (INS) | VAF 17/96 reads (18%) | catalogued as rs759630213; called by mutect2, pindel, varscan2
- MAN2B2 | c.265T>A p.S89T | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.036); catalogued as COSV53452496; called by muse, mutect2, varscan2
- MAP1B | c.7196G>A p.R2399Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs144647263; called by muse, mutect2, varscan2
- MAP2 | c.4190G>T p.R1397M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52288976; called by muse, mutect2, varscan2
- MAP2K7 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1445100216, COSV67608063; called by muse, mutect2, varscan2
- MAP2K7 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67608070; called by muse, mutect2, varscan2
- MAP3K12 | c.2555G>A p.R852Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs369434136; called by muse, mutect2, varscan2
- MAP4K1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.103); catalogued as COSV67709987; called by muse, mutect2, varscan2
- MAP9 | c.1490dup p.N497Kfs*6 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | catalogued as rs778055136; called by mutect2, varscan2
- MAPKBP1 | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52960693; called by muse, mutect2
- MAPT | c.1055C>T p.T352I (on ENST00000262410 / NM_001377265.1; = p.T277I on NM_016835.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV52239693; called by muse, mutect2, varscan2
- MARK2 | c.1781G>A p.R594Q (on ENST00000402010 / NM_001039469.2; = p.R539Q on NM_004954.5) | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV59282742; called by muse, mutect2, varscan2
- MARVELD3 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs967930889, COSV51704630; called by muse, mutect2
- MATK | c.362+1G>A p.X121_splice (on ENST00000310132 / NM_139355.3; = p.X122_splice on NM_002378.4) | Splice Site (SNP) | VAF 16/60 reads (27%) | catalogued as rs770288095, COSV59554101; called by muse, mutect2, varscan2
- MBD3 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV50083457, COSV50084158; called by muse, mutect2, varscan2
- MBD3L1 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59775887; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 23/106 reads (22%) | catalogued as rs558765093; called by mutect2, varscan2
- MBD6 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs773976149, COSV60764932, COSV60765446; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 57/100 reads (57%) | catalogued as rs746267361; called by mutect2, varscan2
- MC3R | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs777906478, CM113223, COSV54763649; called by muse, mutect2, varscan2
- MCC | c.2452_2454del p.E818del | In Frame Del (DEL) | VAF 24/81 reads (30%) | catalogued as rs769125294; called by pindel, varscan2
- MDC1 | c.5948T>C p.L1983P | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64524338; called by muse, mutect2
- MDGA1 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51795155, COSV51797625; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MDN1 | c.6335G>A p.R2112Q | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs143104857; called by muse, mutect2, varscan2
- MDN1 | c.5971A>G p.I1991V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65520807; called by muse, mutect2, varscan2
- ME1 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757421355, COSV63838920; called by muse, mutect2, varscan2
- MED14 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as rs756077240, COSV61356708; called by muse, mutect2, varscan2
- MED23 | c.2276dup p.N759Kfs*7 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs765921048; called by mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MEGF8 | c.410T>C p.F137S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV52082558; called by muse, mutect2
- MEIS3 | c.448-3dup | Splice Region (INS) | VAF 9/39 reads (23%) | catalogued as rs754589852; called by mutect2, varscan2
- METTL4 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV60603413; called by muse, mutect2, varscan2
- MEX3A | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV68479062; called by muse, mutect2, varscan2
- MFSD13A | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773212035, COSV53267070; called by muse, mutect2, varscan2
- MGA | c.3211T>C p.C1071R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54952851; called by muse, mutect2, varscan2
- MGAM | c.5354A>T p.N1785I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV72074520; called by muse, mutect2, varscan2
- MICAL2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763470102, COSV56319666; called by muse, mutect2, varscan2
- MIP | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57510924; called by muse, mutect2, varscan2
- MKKS | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV61398466; called by muse, mutect2
- MKNK2 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs769198683, COSV51731964; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 34/68 reads (50%) | catalogued as rs751465048; called by mutect2, varscan2
- MLLT6 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774325820; called by muse, mutect2, varscan2
- MMP2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1351967941, COSV54600497; called by muse, mutect2, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as rs778232663; called by mutect2, varscan2
- MPP6 | c.917dup p.K307Efs*14 | Frame Shift Ins (INS) | VAF 32/104 reads (31%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRGPRX1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs1364627192, COSV57106743; called by muse, mutect2, varscan2
- MROH2B | c.4114del p.I1372Sfs*5 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs756600463; called by mutect2, varscan2
- MSH3 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763873895, COSV54150626; called by muse, mutect2, varscan2
- MTA1 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.091); catalogued as COSV58756916; called by muse, mutect2, varscan2
- MTCL1 | c.4574C>T p.T1525M (on ENST00000306329 / NM_001378206.1; = p.T1206M on NM_015210.4) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs377453546; called by muse, mutect2, varscan2
- MTHFD1 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as rs750902671, COSV53699887; called by muse, mutect2, varscan2
- MTHFD2L | c.224T>G p.V75G (on ENST00000395759 / NM_001144978.2; = p.V17G on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV57467075; called by muse, mutect2, varscan2
- MTUS2 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs759235281, COSV54986372; called by muse, mutect2, varscan2
- MUC16 | c.23177C>T p.A7726V | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1437444610, COSV67461987; called by muse, mutect2, varscan2
- MUC16 | c.1814T>C p.V605A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.024); catalogued as COSV67461988; called by muse, mutect2, varscan2
- MUSK | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs777865246, COSV51884328, COSV51886983; called by muse, mutect2, varscan2
- MYADM | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs780357518, COSV61238617; called by muse, mutect2, varscan2
- MYH11 | c.5261C>T p.A1754V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs904032269, COSV55550952; ClinVar: uncertain significance; called by muse, mutect2
- MYH14 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1005071052, COSV51815545; called by muse, mutect2, varscan2
- MYH14 | c.5381G>A p.R1794H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754861302, COSV51815568, COSV51821154; called by muse, mutect2, varscan2
- MYH2 | c.4330G>A p.A1444T | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs142908651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.5578G>A p.D1860N | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757115211, COSV60608759; called by muse, mutect2, varscan2
- MYO16 | c.3756C>A p.S1252R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV62749346; called by muse, mutect2, varscan2
- MYO1F | c.2218G>A p.V740I | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs908681220, COSV57794378; called by muse, mutect2, varscan2
- MYOC | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs200120115, CM021645; called by muse, mutect2, varscan2
- MYOM1 | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs922677098, COSV55290553; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAA40 | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.131); catalogued as COSV58160874; called by muse, mutect2, varscan2
- NAV3 | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV57075988; called by muse, mutect2, varscan2
- NBAS | c.1141dup p.I381Nfs*4 | Frame Shift Ins (INS) | VAF 10/25 reads (40%) | catalogued as rs772472509; called by mutect2, varscan2
- NCAN | c.3653del p.P1218Lfs*23 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as COSV53049957; called by mutect2, pindel, varscan2
- NCAPD2 | c.3165G>T p.Q1055H | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59698998; called by muse, mutect2, varscan2
- NCAPD3 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1398377255, COSV73258353; called by muse, mutect2, varscan2
- NCBP2 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV58317504; called by muse, mutect2, varscan2
- NCBP2 | c.122C>T p.T41M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs760696628, COSV58317512; called by muse, mutect2, varscan2
- NCEH1 | c.313dup p.S105Kfs*16 (on ENST00000538775; = p.S73Kfs*16 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 40/104 reads (38%) | catalogued as rs759087510; called by mutect2, varscan2
- NCKAP5L | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1158585452, COSV60129150; called by muse, mutect2, varscan2
- NCLN | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV55742417; called by muse, mutect2, varscan2
- NCOA1 | c.3914C>T p.T1305M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as rs770279405, COSV56042843; called by muse, mutect2, varscan2
- NCOA6 | c.3353C>T p.P1118L | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs767151504, COSV62861256; called by muse, mutect2, varscan2
- NCOA6 | c.1013T>C p.M338T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV62863139; called by muse, mutect2, varscan2
- NEB | c.15124C>T p.R5042C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762552898, COSV50814710; called by mutect2, varscan2
- NEB | c.10979G>T p.R3660M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51156616; called by muse, mutect2, varscan2
- NEFL | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV55336829; called by muse, mutect2, varscan2
- NFATC1 | c.1091C>G p.A364G | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV53699359; called by muse, mutect2, varscan2
- NFE2 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV56455741; called by muse, mutect2, varscan2
- NFIC | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 95/426 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as COSV59411999; called by muse, mutect2, varscan2
- NFIX | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62176913; called by muse, mutect2, varscan2
- NHSL2 | c.1923del p.K641Nfs*53 (on ENST00000510661; = p.K1007Nfs*53 on NM_001013627.2) | Frame Shift Del (DEL) | VAF 31/56 reads (55%) | catalogued as rs755845942; called by mutect2, pindel, varscan2
- NINL | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs369056472; called by muse, mutect2, varscan2
- NIPBL | c.5164A>G p.N1722D | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as CM1212226, COSV56949842; called by muse, mutect2, varscan2
- NLGN1 | c.242T>A p.L81H | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64331439, COSV64331546, COSV64347082; called by muse, mutect2
- NLRP12 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as rs1319286947, COSV60746443; called by muse, mutect2, varscan2
- NOL6 | c.1783G>A p.G595R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558572103, COSV53041146; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NPHP4 | c.2039C>T p.T680M | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370238544; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs774343392; called by mutect2, varscan2
- NRBP2 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59918264; called by muse, mutect2, varscan2
- NRXN1 | c.4258T>C p.Y1420H | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV60496299; called by muse, mutect2, varscan2
- NSFL1C | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs6105156, COSV53793180; called by muse, mutect2, varscan2
- NT5C1A | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.244); catalogued as rs763507322, COSV52494048; called by muse, mutect2, varscan2
- NUCB1 | c.97dup p.A33Gfs*11 | Frame Shift Ins (INS) | VAF 12/88 reads (14%) | catalogued as rs771817906; called by mutect2, pindel, varscan2
- NWD1 | c.4259G>A p.R1420H | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs375293723; called by muse, mutect2, varscan2
- NXF1 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs780326943, COSV53672318, COSV53677034; called by muse, mutect2, varscan2
- NXF3 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV67703321; called by muse, mutect2
- NXPH3 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781447574, COSV60872147; called by muse, mutect2, varscan2
- NYAP1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs138038785; called by muse, mutect2, varscan2
- OBSCN | c.13115C>T p.T4372I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV52768055; called by muse, mutect2
- OBSCN | c.18680C>T p.A6227V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs756024007, COSV52768075; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- ODF3L2 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.73); catalogued as rs770427855, COSV59622977; called by muse, mutect2, varscan2
- OGG1 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs750447639, COSV56537920; called by muse, mutect2, varscan2
- OPRM1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.233); catalogued as rs202015908, COSV57675811; called by muse, mutect2, varscan2
- OR1E2 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV50265563; called by muse, mutect2, varscan2
- OR1M1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772434948, COSV70036801; called by muse, mutect2, varscan2
- OR2B6 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs372830614; called by muse, mutect2, varscan2
- OR2W3 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV64456687; called by muse, mutect2, varscan2
- OR4A16 | c.246C>G p.D82E | Missense Mutation (SNP) | VAF 63/197 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV59042807; called by muse, mutect2, varscan2
- OR4C15 | c.188A>C p.E63A (on ENST00000314644; = p.E9A on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as COSV58951804, COSV58951861; called by muse, mutect2, varscan2
- OR4D11 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755431598, COSV57585431; called by muse, mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 84/382 reads (22%) | catalogued as rs1566497842; called by mutect2, pindel, varscan2
- OR51T1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs144368286; called by muse, mutect2, varscan2
- OR5AK2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs757906890, COSV58803755; called by muse, mutect2, varscan2
- OR6T1 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs755409697, COSV58306666; called by muse, mutect2, varscan2
- OR7D4 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs112089905, COSV58071510; called by muse, mutect2, varscan2
- OTUB1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1256016375, COSV55359576; called by muse, mutect2, varscan2
- P2RX3 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV54442322; called by muse, mutect2, varscan2
- P2RX5 | c.385T>C p.C129R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56591588; called by muse, mutect2, varscan2
- P3H2 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs558211251, COSV60020878; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs763394045; called by mutect2, varscan2
- PACRG | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV61303445; called by muse, mutect2, varscan2
- PADI2 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.969); catalogued as COSV64945760; called by muse, mutect2
- PAGR1 | c.483-2A>G p.X161_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56189484; called by muse, mutect2, varscan2
- PAK4 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs988897964, COSV58944787; called by muse, mutect2, varscan2
- PANK4 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.131); catalogued as rs1437919489, COSV65866541; called by muse, mutect2, varscan2
- PANK4 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as rs370719786, COSV65866601; called by muse, mutect2, varscan2
- PAPOLG | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.518); catalogued as rs1236443444, COSV53182434; called by muse, mutect2, varscan2
- PARP14 | c.4346T>C p.L1449P | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71734549; called by muse, mutect2, varscan2
- PARP2 | c.640-2A>G p.X214_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV51638778; called by muse, mutect2, varscan2
- PASK | c.1690A>C p.M564L | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV52151608; called by muse, mutect2, varscan2
- PAX8 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54507997; called by muse, mutect2, varscan2
- PCDH10 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52092575; called by muse, mutect2, varscan2
- PCDH17 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV64973557, COSV64976754; called by muse, varscan2
- PCDH7 | c.1706A>G p.E569G | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62338374; called by muse, mutect2, varscan2
- PCDHA13 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as COSV56491140; called by muse, mutect2, varscan2
- PCDHA4 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1562206749, COSV63540728, COSV63544178; called by muse, mutect2, varscan2
- PCDHB11 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61311178; called by muse, mutect2, varscan2
- PCDHB6 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50692259; called by muse, varscan2
- PCDHGA5 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.775); catalogued as COSV53935263; called by muse, mutect2
- PCED1B | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as rs1565622058, COSV71395128; called by muse, mutect2, varscan2
- PCGF1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 86/326 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.074); catalogued as rs201383050, COSV52042980; called by muse, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PDCD4 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs1275158753, COSV54522595; called by muse, mutect2
- PDGFD | c.510+2T>C p.X170_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56376095; called by muse, mutect2, varscan2
- PDIA5 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV60248751; called by muse, mutect2, varscan2
- PDXDC1 | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 39/171 reads (23%) | catalogued as rs754783898, COSV55074165; called by muse, mutect2, varscan2
- PELO | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV50880735; called by muse, mutect2, varscan2
- PER3 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1473222206, COSV62705488; called by muse, mutect2, varscan2
- PEX16 | c.565T>C p.W189R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53800931, COSV53801823; called by muse, mutect2, varscan2
- PEX6 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55102832; called by muse, mutect2, varscan2
- PFKFB1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 92/125 reads (74%) | catalogued as rs372795411, COSV66628173; called by muse, mutect2, varscan2
- PHF14 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as COSV68855122; called by mutect2, varscan2
- PHYKPL | c.146A>C p.E49A | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.081); catalogued as COSV57423959; called by muse, varscan2
- PIGL | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56685224; called by muse, mutect2, varscan2
- PIGQ | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs559762174, COSV50313117; called by muse, mutect2, varscan2
- PIGV | c.117A>C p.E39D | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50291266; called by muse, mutect2, varscan2
- PIK3C2A | c.3046G>T p.D1016Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314646321, COSV56402218; called by muse, mutect2, varscan2
- PKDREJ | c.6601A>G p.R2201G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53548840; called by muse, mutect2, varscan2
- PLA2R1 | c.3827C>T p.A1276V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291430637, COSV51777750; called by muse, mutect2, varscan2
- PLAGL2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs760026877, COSV55788124; called by muse, mutect2, varscan2
- PLAT | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs140012141; called by muse, mutect2, varscan2
- PLCG1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs777319797, COSV54817933; called by muse, mutect2, varscan2
- PLD4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1334077652, COSV66914757, COSV66915138; called by muse, mutect2, varscan2
- PLEC | c.6169C>T p.R2057W (on ENST00000322810 / NM_201380.4; = p.R1947W on NM_000445.5) | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs781860739, COSV59618590; called by muse, mutect2, varscan2
- PLEKHF1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71410042; called by muse, mutect2, varscan2
- PLK4 | c.2565G>T p.M855I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV54637241; called by muse, mutect2, varscan2
- PLOD2 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs142041189, COSV51467230; called by muse, mutect2, varscan2
- PLPPR2 | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52259599; called by muse, mutect2, varscan2
- PLXNA1 | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 171/390 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV52525348; called by muse, mutect2, varscan2
- PLXNA2 | c.2395G>T p.V799F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV65440082; called by muse, varscan2
981 further variants in this file (584 protein-altering or splice-affecting, 364 silent, 33 other) are not listed here.
